Somatic mutation profile of tumor specimen 0DJC36 from CCDI case PBBUSK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical choroid plexus papilloma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 0.5 years (184 days).
Specimen 0DJC36: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a209a93-b70d-4f8e-9f61-a8d056bd3000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJBLN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e49172e9-93bc-428d-bc08-aadd6698e8ab

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC090517.4 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 354/620 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777989146, COSV50996138; called by muse, varscan2
- IL9R | c.659A>T p.H220L | Missense Mutation (SNP) | VAF 225/514 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99729737; called by mutect2, varscan2
- DENR | c.*98A>G | 3'UTR (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 22/207 reads (11%) | called by muse, varscan2
